RC case RC-B65Q — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4482bf69-d847-4d3e-a0a2-7ececd9b936d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1928; Vital status: Dead; Days to death: 475 days (1.3 years); Year of death: 2015.

Diagnoses (1)
1. Prolymphocytic leukemia, T-cell type: ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 85.7 years (31,289 days); Year of diagnosis: 2013; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Follow-up contact recording only the day: day 475.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hematologic Disorder, NOS.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Gout / Benign Thyroid Nodule / Benign Prostatic Hyperplasia.
- Timepoint category: Initial Diagnosis; Weight: 85.6 kg; Height: 170 cm; BMI: 29.6.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 3.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample RC-B65Q-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65Q-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
